Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A12H, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A12H-01A (Primary Tumor).

[page 1 of 5]
Clinical Diagnosis & History:
Palpable right breast mass with core biopsy showing invasive cancer.

Specimens Submitted:

- 1: SP: Sentinel node #1, level 1, right axilla
- 2: SP: Sentinel node #2, level 1, right axilla
- 3: SP: Sentinel node #3, level 2, right axilla
- 4: SP: Right breast
- 5: SP: Sentinel nodes #4 and #5, level 1, right axilla
- 6: SP: Non-sentinel nodes right axilla

DIAGNOSIS:

- 1) LYMPH NODE, SENTINEL #1 LEVEL I RIGHT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- ADDITIONAL H/E LEVELS AND CYTOKERATIN (AE1:AE3) IMMUNOSTAINS ARE ALSO NEGATIVE FOR METASTATIC TUMOR.
- 2) LYMPH NODE, SENTINEL #2 LEVEL I RIGHT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- ADDITIONAL H/E LEVELS AND CYTOKERATIN (AE1:AE3) IMMUNOSTAINS ARE ALSO NEGATIVE FOR METASTATIC TUMOR.
- 3) LYMPH NODE, SENTINEL #3 LEVEL II RIGHT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- ADDITIONAL H/E LEVELS AND CYTOKERATIN (AE1:AE3) IMMUNOSTAINS ARE ALSO NEGATIVE FOR METASTATIC TUMOR.
- 4) BREAST, RIGHT; TOTAL MASTECTOMY:
- INVASIVE DUCTAL CARCINOMA, MODERATELY DIFFERENTIATED WITH SOLID-PAPILLARY GROWTH PATTERN AND MUCINOUS DIFFERENTIATION, MEASURING 2.2 CM IN LARGEST DIMENSION MICROSCOPICALLY.
- FOCAL DUCTAL CARCINOMA IN SITU (DCIS), SOLID-PAPILLARY, SOLID AND CRIBRIFORM TYPES WITH LOW TO INTERMEDIATE NUCLEAR GRADE AND MINIMAL NECROSIS.
- NIPPLE, SKIN AND SURGICAL MARGINS ARE NEGATIVE FOR TUMOR.
- NO CONVINCING EVIDENCE OF LYMPHOVASCULAR INVASION.
- PREVIOUS BIOPSY SITE CHANGES, STROMAL FIBROSIS AND ATROPHY.
- IMMUNOHISTOCHEMICAL STAINS WERE PERFORMED ON FORMALIN-FIXED TISSUE WITH THE FOLLOWING RESULTS FOR INVASIVE CARCINOMA (BLOCK "T3"):

** Continued on next page **

1CD-0-3

carcinoma, infiltrating ductal mixed w/ other types
(mucinous + solid pap) 8523/3

Site: breast, nos 450.9 pw 10/22/11

Diagnostic discrepancy		
ICD-O3 discrepancy		
Pathologic discrepancy		
Genomic discrepancy		
Cell line (for cell)		
Review/initials		

10/22/11

[page 2 of 5]
ESTROGEN RECEPTOR (6F11,
WITH STRONG INTENSITY
PROGESTERONE RECEPTOR (1E2;
WITH MODERATE INTENSITY
HER-2/NEU (Herceptest;
INTENSITY OF 0)

Page 4 of 5
100% NUCLEAR STAINING

5% NUCLEAR STAINING

NEGATIVE (STAINING

- 5) LYMPH NODES, SENTINEL #4 AND #5 LEVEL I RIGHT AXILLA; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 6) LYMPH NODES, NON-SENTINEL RIGHT AXILLA; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

- 1) The specimen is received fresh for frozen section consultation,
labeled "Sentinel node #1, level one, right axilla" and consists of a single
pink tan firm lymph node measuring 1.2 cm in greatest dimension. Bisected
and entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

- 2) The specimen is received fresh for frozen section consultation,
labeled "Sentinel node #2, level 1, right axilla" and consists of a pink tan
firm lymph node measuring 0.5 cm. Entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

1

- 3) The specimen is received fresh for frozen section consultation,
labeled "Sentinel node #3, level 2, right axilla" and consists of a single
pink tan firm lymph node measuring 0.8 cm. Bisected and entirely submitted
for frozen section.

** Continued on next page **

[page 3 of 5]
3

4) The specimen is received fresh labeled, "Right breast, stitch marks axillary tail" and consists of a breast measuring 25.2 x 24.6 x 3.2 cm with overlying skin ellipse measuring 15.1 x 14.6 cm. Situated centrally on the skin surface is an everted nipple measuring 1.1 cm and areola measuring 4.1 x 4.2 cm. There is no scar on the skin surface. A suture demarcates the axillary aspect. The posterior surface of the breast is inked black and the axillary aspect is inked green. The specimen is serially sectioned to reveal a 2.5 x 2.2 x 2.3 cm well circumscribed, brown, focally hemorrhagic mass located at the 11 o'clock axis (upper outer quadrant), 0.9 cm from the deep margin. A metallic clip is identified adjacent to this lesion. Additionally, a 1.7 x 1.5 x 1.5 cm fibrous area with areas of hemorrhage and necrosis is present inferior to the 2.5 cm mass in the 11 o'clock axis in the retroareolar region. No other masses or lesions are grossly identified. The cut surfaces are composed of 60% fatty and 40% fibrous tissue. Sectioning of the axillary aspect reveals no grossly identifiable lymph nodes. Tissue submitted for TPS. Representative sections are submitted.

Summary of sections:

N - nipple
NB - nipple base
S - skin
D - deep margin
T - tumor
UIQ - upper inner quadrant
LIQ - lower inner quadrant
UOQ - upper outer quadrant
LOQ - lower outer quadrant
RA - retroareolar fibrous tissue

5) The specimen is received in formalin labeled, "Sentinel nodes #4 and 5, level 1, right axilla", and consists of two tan lymph nodes measuring 2 cm and 0.8 cm respectively. Both are bisected and entirely submitted.

Summary of sections:

LLN - larger lymph node (bisected and submitted in two cassettes)
SLN - smaller lymph node

6) The specimen is received in formalin, labeled "Non-sentinel nodes right axilla" and consists of multiple pink tan firm lymph nodes ranging from 0.2 cm to 2.1 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes
SLN - bisected lymph node
LLN - largest lymph node bisected and submitted in two cassettes

** Continued on next page **

[page 4 of 5]
4

Summary of Sections:

Part 1: SP: Sentinel node #1, level 1, right axilla

Block	Sect.	Site	PCs
1		FSC	1

Part 2: SP: Sentinel node #2, level 1, right axilla

Block	Sect.	Site	PCs
1		FSC	1

Part 3: SP: Sentinel node #3, level 2, right axilla

Block	Sect.	Site	PCs
1		FSC	1

Part 4: SP: Right breast

Block	Sect.	Site	PCs
1		D	1
1		LIQ	1
1		LOQ	1
1		N	1
2		NB	1
1		RA	2
6		S	1
1		T	6
1		UIQ	1
1		VOQ	1

Part 5: SP: Sentinel nodes #4 and #5, level 1, right axilla

Block	Sect.	Site	PCs
2		LLN	2
1		SLN	1

Part 6: SP: Non-sentinel nodes right axilla

Block	Sect.	Site	PCs
1		BLN	1
2		LLN	2
1		LN	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

** Continued on next page **

[page 5 of 5]
1) FROZEN SECTION DIAGNOSIS: SP: SENTINEL NODE #1, LEVEL 1,
RIGHT AXILLA : BENIGN LYMPH NODE.
PERMANENT DIAGNOSIS: SAME

2) FROZEN SECTION DIAGNOSIS: SP: SENTINEL NODE #2, LEVEL 1,
RIGHT AXILLA : BENIGN LYMPH NODE, MAINLY FIBROFATTY WITH SCANTY
LYMPHOID TISSUE.
PERMANENT DIAGNOSIS: SAME

3) FROZEN SECTION DIAGNOSIS: SP: SENTINEL NODE #3, LEVEL 2,
RIGHT AXILLA : BENIGN LYMPH NODE.
PERMANENT DIAGNOSIS: SAME

Note: The diagnoses given in this section pertain only to the tissue sample
examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: SP: SENTINEL NODE #1, LEVEL 1,
RIGHT AXILLA : BENIGN LYMPH NODE. (
PERMANENT DIAGNOSIS: SAME

2) FROZEN SECTION DIAGNOSIS: SP: SENTINEL NODE #2, LEVEL 1,
RIGHT AXILLA : BENIGN LYMPH NODE, MAINLY FIBROFATTY WITH SCANTY
LYMPHOID TISSUE.
PERMANENT DIAGNOSIS: SAME

3) FROZEN SECTION DIAGNOSIS: SP: SENTINEL NODE #3, LEVEL 2,
RIGHT AXILLA : BENIGN LYMPH NODE.
PERMANENT DIAGNOSIS: SAME

** End of Report **

Source: NCI Genomic Data Commons file 5372400c-1429-4246-8358-e4cec95aaef0 (TCGA-AO-A12H.2FDFCEB5-74F7-417E-9FD1-ECC81B27803B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).